Somatic mutation profile of tumor specimen TARGET-10-PARNXJ-09A (aliquot TARGET-10-PARNXJ-09A-01D) from TARGET case TARGET-10-PARNXJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,760 days).
Specimen TARGET-10-PARNXJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb23420d-90d5-44f8-b567-e1c4ce99417f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNXJ-10A (Blood Derived Normal), aliquot TARGET-10-PARNXJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dcc56ec-e658-4756-9e10-20ee0c415dcc

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 3, Intron 2, Splice Site 2, 3'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 18/170 reads (11%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2
- BEND3 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs781840667, COSV100944594, COSV64681471; called by muse, mutect2, varscan2
- CDH3 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs773298688, COSV50561490; called by muse, mutect2, varscan2
- CDH8 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 94/194 reads (48%) | catalogued as rs1176454679, COSV54877670; called by muse, mutect2, varscan2
- CFTR | c.3770T>A p.F1257Y | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV50066484; called by muse, mutect2, varscan2
- COQ2 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV61021811; called by muse, mutect2
- FER1L6 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs370359921; called by muse, mutect2, varscan2
- HIVEP2 | c.266_267insATCAATCTCCG p.P91Ifs*72 | Frame Shift Ins (INS) | VAF 16/147 reads (11%) | catalogued as COSV50020958; called by mutect2, pindel
- HS3ST5 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as rs144143119; called by muse, mutect2, varscan2
- LAMB3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs145575474, COSV61916499, COSV61918706; called by muse, mutect2, varscan2
- NOX4 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as rs925412176, COSV54456709; called by muse, mutect2, varscan2
- PPM1J | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs1485479499, COSV58551811; called by muse, mutect2, varscan2
- SENP6 | c.3020G>T p.R1007I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64185363; called by muse, mutect2, varscan2
- SYNGAP1 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV53382931; called by muse, mutect2, varscan2
- USP7 | c.611delinsGG p.A204Gfs*48 | Frame Shift Ins (INS) | VAF 21/68 reads (31%) | catalogued as COSV61215618, COSV61217599; called by mutect2*, pindel, varscan2*
- WRAP73 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs770807708, COSV54561770; called by muse, mutect2
- ZNF781 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs747283649, COSV62201903; called by muse, mutect2, varscan2
- OR9G1 | c.7_8dup p.S4Gfs*6 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- USP7 | c.611+1dup p.X204_splice | Splice Site (INS) | VAF 31/87 reads (36%) | called by mutect2, varscan2
- DSCAML1 | c.417C>T p.N139= (on ENST00000321322; = p.N79= on NM_020693.4) | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs889334508, COSV100355146, COSV58400300; called by muse, mutect2, varscan2
- OGDHL | c.147C>A p.S49= | Silent (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- PDZD4 | c.351G>A p.P117= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs781966669, COSV51252535; called by muse, mutect2, varscan2
- SLC18A2 | c.420C>T p.T140= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs931830645, COSV53689165; called by muse, mutect2
- XDH | c.1884G>A p.K628= | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- COL7A1 | c.8227-21C>T | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- MIR380 | n.59C>A | RNA (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- ROBO3 | c.*62T>C | 3'UTR (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100127310; called by muse, mutect2
- ZFHX3 | c.-897+3496C>T | Intron (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
